Somatic mutation profile of tumor specimen 0DENCJ from CCDI case PBBPYD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 15.1 years (5,533 days).
Specimen 0DENCJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1eba6452-2e5b-499f-a97f-1f0384701eec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DENBW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3f1b193-1341-4ad3-826b-e031d7d60117

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1, Splice Site 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAH2 | c.1406T>C p.F469S | Missense Mutation (SNP) | VAF 82/1384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RECQL4 | c.85-1G>A p.X29_splice | Splice Site (SNP) | VAF 122/430 reads (28%) | called by muse, mutect2, varscan2
- MYH13 | c.3384G>A p.A1128= | Silent (SNP) | VAF 137/612 reads (22%) | catalogued as rs373348807; called by muse, mutect2, varscan2
- NHSL2 | c.795T>C p.S265= (on ENST00000510661; = p.S631= on NM_001013627.2) | Silent (SNP) | VAF 21/399 reads (5%) | called by muse, mutect2
- LEKR1 | c.*605C>T | 3'UTR (SNP) | VAF 274/1266 reads (22%) | catalogued as rs1284696106; called by muse, mutect2, varscan2
- SCN1B | c.41-34G>A | Intron (SNP) | VAF 20/133 reads (15%) | catalogued as rs1294515950; called by muse, mutect2
